Gene-level copy-number profile of tumor specimen TCGA-VS-A9U5-01A from TCGA case TCGA-VS-A9U5, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 57.9 years (21,149 days).
Specimen TCGA-VS-A9U5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.d631dcba-6d88-40d0-bf0a-d9854e72ed83.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9U5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9275e02c-a14e-4ed8-8163-c4573bcddb35

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 742; copy number 2: 15,034; copy number 3: 14,130; copy number 4: 22,674; copy number 5: 6,100; copy number 6: 402; copy number 7: 179; copy number 8: 41; copy number 9: 188; copy number 11: 69; copy number 12: 55; copy number 15: 15; copy number 16: 46; copy number 20: 11; copy number 25: 18; copy number 31: 104; copy number 37: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9U5-01A-11D-A42N-01): tumor purity 0.56, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 509 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:212,545,694–212,620,777, 4 genes, copy number 15 (within-gene range 4–15): LINC01740, AC092803.1, AC092803.4, ATF3.
- chr11:81,821,272–82,718,299, 1 gene, copy number 20 (within-gene range 2–20): MIR4300HG.
- chr11:81,890,741–83,423,516, 33 genes, copy number 11–20: MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr11:83,643,602–83,815,263, 3 genes, copy number 11: DLG2-AS2, AP002370.1, LDHAL6DP.
- chr11:101,765,935–104,252,651, 55 genes, copy number 12: AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1.
- chr14:30,734,926–40,905,513, 171 genes, copy number 16–37 (broad region; genes not listed).
- chr16:9,365,540–14,953,120, 145 genes, copy number 9–11 (within-gene range 2–11) (broad region; genes not listed).
- chr16:14,988,259–15,056,079, 4 genes, copy number 9 (within-gene range 8–9): AC138932.2, MIR1972-1, AC138932.4, NTAN1.
- chr17:39,603,536–39,747,291, 11 genes, copy number 15: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr22:29,788,609–31,530,634, 81 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr22:31,490,150–31,491,022, 1 gene, copy number 9: AL096701.4.

Autosomal genes at a single copy (total copy number 1): 742. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
